Surgical pathology report (de-identified scan), TCGA case TCGA-M7-A720, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of North Carolina, specimen TCGA-M7-A720-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Prostate, robotic prostatectomy

Tumor histologic type: prostatic adenocarcinoma

Tumor grade (Gleason system): 3 + 3

Approximate percentage of prostate involved by tumor: 20%

Extent of tumor:

Location of tumor involvement in prostate: scattered tumor present throughout prostate

Confinement/non-confinement of tumor within the prostatic capsule: confined within capsule

Lymphovascular space invasion: not identified

Seminal vesicles (invasion of muscular wall required):
uninvolved by tumor

Histologic assessment of surgical margins: uninvolved by tumor

Other significant findings: benign prostatic hyperplasia

Lymph nodes: none submitted

AJCC Staging:

pT2c

pNX

This staging information is based on this pathologic specimen and may be incomplete. A comprehensive review of all available information is recommended to determine final staging.

Clinical History:

-year-old male with prostate cancer.

Gross Description:

Specimen fixation: formalin

Type of specimen(s) received: robot assisted prostatectomy

66012 ICD-O-3
Adenocarcinoma, acinar
path 8140/3
Adenocarcinoma NOS
8140/3
Site Prostate NOS
C61.9
JW 8/12/13

[page 2 of 2]
Size of specimen: 4.0 cm medial to lateral x 3.7 cm superior to inferior x 3.6 cm anterior to posterior

Weight of specimen: 25.8 grams

Orientation: Right=blue, left=black, apex=yellow, bladder neck=red

Size and description of other organs or structures: There is 2.4 x 0.5 cm of attached right vas deferens and 2.8 x 0.6 x 0.5 cm of attached right seminal vesicle.

There is 1.8 x 0.6 cm of attached left vas deferens, and 1.5 x 0.8 x 0.5 cm of attached left seminal vesicle.

Gross description of prostate: Sectioning from apex towards base reveals a moderate of periurethral nodularity and an ill-defined yellow attenuated area in the right posterior lobe near the base of the specimen.

Digital photograph taken: not taken

Tissue given to

Tumor is given to

Block summary:

(Inking: right=blue, left=black, apex=yellow, bladder neck=red)

A1 - right apex, serially sectioned perpendicular to the inked surgical margin
A2-A12 - right prostate, apex towards base, respectively
A13 - right bladder neck margin, sectioned perpendicular to the inked surgical margin
A14 - right vas deferens margin of resection and representative section from right seminal vesicle
A15 - left apex, serially sectioned perpendicular to the inked surgical margin
A16-A27 - left prostate, submitted from apex towards base, respectively
A28 - left bladder neck, sectioned perpendicular to the inked surgical margin
A29 - left vas deferens margin of resection and representative section of left seminal vesicle

INMIA Discrepancy		☒
Metastatic/Synchronous Primary Nodules		☒

Source: NCI Genomic Data Commons file 6f384a1a-7d2a-4b66-a158-493dfbe63214 (TCGA-M7-A720.65D5D425-D41A-4E98-AA86-119F3BE1D3CE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).